Gene-level copy-number profile of tumor specimen HCM-CSHL-0857-C19-06A from HCMI case HCM-CSHL-0857-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,244 days).
Specimen HCM-CSHL-0857-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e8f9dce9-96d6-405b-883f-1b3d32147296.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0857-C19-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/14f8fe0a-2eb5-46b9-baac-8229963e3036

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 1,617; copy number 2: 13,765; copy number 3: 28,061; copy number 4: 9,084; copy number 5: 4,207; copy number 6: 1,088; copy number 7: 510; copy number 8: 1; copy number 13: 46; copy number 20: 15.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:19,878,555–19,988,117, 8 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 572 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:6,748,131–7,513,644, 20 genes, copy number 7 (within-gene range 6–7): GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2, OR2D3, ZNF215, ZNF214, NLRP14, RBMXL2, AC027804.1, MIR302E, SYT9, AC107884.1, OLFML1.
- chr11:76,186,325–78,582,156, 67 genes, copy number 7–20 (broad region; genes not listed).
- chr20:7,831,798–8,043,512, 5 genes, copy number 7: AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:8,097,824–8,099,774, 1 gene, copy number 7: PHKBP1.
- chr20:38,127,385–61,083,750, 479 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
